Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-AA6D, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-AA6D-01A (Primary Tumor).

[page 1 of 2]
Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

- 1 - "Hepatogastric ligament".
- Fragment of fibroconnective tissue free of neoplasia.

- 2 - Omentum:
- Absence of neoplasia.

- 3 - Product of gastrectomy:
- Adenocarcinoma characterized as follows:
- Location: gastric antrum
- Type III of Borman's classification
- Histological pattern(s) observed:
- tubular
- solid
- Histologic Grade II - moderately differentiated
- Intestinal type of Lauren's classification
- Measure the longest axis of the tumor: 7.0
- Ulceration:
- present
- Compromise of:
- adjacent adipose tissue
- Type of tumor invasion
- spiculated
- Inflammatory reaction:
- moderate
- Tumor implantation in peri-visceral adipose tissue:
- not detected
- Proximal margin.
- Free of neoplastic involvement.
- Measure: 14.0
- Distal margin.
- Free of neoplastic involvement.
- Measure: 3.0
- Neural infiltration:
- not detected
- Lymphatic vascular invasion:
- not detected

~~CICF~~ ICD-O-3
Adenocarcinoma, tubular 82113
path
Adenocarcinoma, tubular & solid 82113 823613
Code to highest 823013
Site: Gastric antrum C16.3
Jan 20/14

[page 2 of 2]
Sanguineous vascular invasion:

not detected

Tumor implantation in soft tissue

not detected

Discrimination of lymph nodes according to the standardization ,
dissected lymph nodes ratio:)

(committed /

F - Chain 1 – right paracardiac: (0/2)

H - Chain 3 - along the lesser curvature: (2/ 11)

N - Chain 7 - along the left gastric artery: (0/2)

Q - Chain 9 - around the celiac trunk: (0/16)

AJ - Chain 110 – inferior para-esophageal: (0/5)

4 - "Eophageal margin".

- Free of neoplasia.

6 - "Second gastric margin."

- Free of neoplasia.

PATHOLOGIC STAGING

Topography	Morphology	Stage
Stomach, NOS	Adenocarcinoma, NOS	pT3 pN1

Criteria	12/23/13	Yes	No

Source: NCI Genomic Data Commons file 52dfa22c-a11d-4680-99a7-39742f8a4a7c (TCGA-VQ-AA6D.C8364730-522B-4F16-9366-902A6F3625C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).